Somatic mutation profile of tumor specimen ALCH-B0AJ-TTP1-A (aliquot ALCH-B0AJ-TTP1-A-1-0-D-A680-36) from ALCHEMIST case ALCH-B0AJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.2 years (29,288 days).
Specimen ALCH-B0AJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e7333d9-7beb-4f6f-b1e2-bdd105682157.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0AJ-NB1-A (Blood Derived Normal), aliquot ALCH-B0AJ-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51b078ba-6a96-4746-8343-1603d9d1554e

The open-access MAF lists 146 somatic variants for this specimen: 95 protein-altering or splice-affecting, 32 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 32, Intron 10, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 3, 3'Flank 3, 5'UTR 2, 3'UTR 2, 5'Flank 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 89/424 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANK1 | c.2800C>A p.L934M | Missense Mutation (SNP) | VAF 94/659 reads (14%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.88); catalogued as CD971978; called by muse, mutect2, varscan2
- ATP11A | c.38del p.Y13Sfs*60 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | catalogued as COSV52108387; called by mutect2, pindel
- ATP2B2 | c.2380G>A p.D794N (on ENST00000352432; = p.D760N on NM_001683.5) | Missense Mutation (SNP) | VAF 57/459 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs781596200, COSV59506745; called by muse, mutect2, varscan2
- C16orf86 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as rs768266159, COSV54753342; called by muse, mutect2, varscan2
- CAPSL | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV68438270; called by muse, mutect2, varscan2
- CENPE | c.5262G>T p.M1754I | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs775856723; called by muse, mutect2, varscan2
- CFH | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62776859; called by muse, mutect2, varscan2
- CFHR1 | c.608-1G>T p.X203_splice | Splice Site (SNP) | VAF 114/274 reads (42%) | catalogued as rs1290679389; called by muse, mutect2, varscan2
- CNTFR | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63634103; called by muse, mutect2, varscan2
- DIRAS2 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 120/784 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65369957; called by muse, mutect2, varscan2
- DMD | c.486C>G p.S162R | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99918231; called by muse, mutect2, varscan2
- EIF3F | c.856G>T p.V286L | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV59142271; called by muse, mutect2
- FAT2 | c.8242G>T p.V2748F | Missense Mutation (SNP) | VAF 41/384 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.697); catalogued as rs747051009; called by muse, mutect2, varscan2
- FMN2 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.987); catalogued as COSV60452833; called by muse, mutect2, varscan2
- FUOM | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs774053362; called by muse, mutect2, varscan2
- GBA3 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72438874; called by muse, varscan2
- GLIPR2 | c.245G>C p.R82T | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as COSV65029768; called by muse, mutect2
- HCAR1 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 83/241 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs759905684, COSV63670882; called by muse, mutect2, varscan2
- IGFLR1 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV53075177; called by muse, mutect2, varscan2
- IGLL5 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 135/1012 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as COSV66536413; called by muse, mutect2, varscan2
- KCNJ1 | c.427G>C p.G143R | Missense Mutation (SNP) | VAF 82/505 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60663130; called by muse, mutect2, varscan2
- KDM5C | c.202dup p.R68Pfs*7 | Frame Shift Ins (INS) | VAF 81/333 reads (24%) | catalogued as rs782600511; called by mutect2, pindel, varscan2
- MARCHF1 | c.310C>T p.R104C (on ENST00000274056; = p.R87C on NM_017923.4) | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs146337383; called by muse, mutect2
- MYLK | c.681C>A p.D227E | Missense Mutation (SNP) | VAF 98/616 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768879568, COSV60622461; called by muse, mutect2, varscan2
- NLRP8 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 65/437 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV99405116; called by muse, mutect2, varscan2
- OR5F1 | c.476A>T p.N159I | Missense Mutation (SNP) | VAF 34/329 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as COSV53548407; called by muse, mutect2
- PPM1E | c.1633C>A p.R545S | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs753162691, COSV57570884, COSV57576381; called by muse, mutect2, varscan2
- PTCD3 | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200261667, COSV54480222; called by muse, mutect2
- RBM10 | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 41/119 reads (34%) | catalogued as COSV61313237; called by muse, mutect2, varscan2
- SAMD9L | c.2591A>G p.K864R | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as rs1213100746; called by muse, mutect2
- SCN2A | c.1924G>T p.G642W | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51839881, COSV51841292; called by muse, mutect2, varscan2
- SLC24A2 | c.1029G>C p.R343S | Missense Mutation (SNP) | VAF 97/640 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99647167; called by muse, mutect2, varscan2
- SPTBN4 | c.4525C>T p.R1509C | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs944748648; called by muse, mutect2, varscan2
- TRANK1 | c.2993A>G p.N998S | Missense Mutation (SNP) | VAF 73/498 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1321601562; called by muse, mutect2, varscan2
- TRPM8 | c.2069C>T p.T690I | Missense Mutation (SNP) | VAF 40/384 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100224035; called by muse, mutect2, varscan2
- TUBA3C | c.685C>A p.R229S | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV67139512; called by muse, mutect2, varscan2
- VWA5A | c.1814A>T p.H605L | Missense Mutation (SNP) | VAF 53/396 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV64411976; called by muse, mutect2, varscan2
- ZNF479 | c.528A>T p.K176N | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV58640133; called by muse, mutect2, varscan2
- ZNF560 | c.1774C>T p.R592* | Nonsense Mutation (SNP) | VAF 27/285 reads (9%) | catalogued as rs746257684; called by muse, mutect2
- ACSF2 | c.1049G>T p.G350V | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ADAMTS7 | c.4883G>T p.C1628F | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ANKRD17 | c.3371C>T p.A1124V | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ARHGEF11 | c.4448C>T p.A1483V | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATL3 | c.865T>A p.F289I | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1S | c.2850C>A p.F950L | Missense Mutation (SNP) | VAF 52/446 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- CDK15 | c.657C>A p.H219Q (on ENST00000652192 / NM_001366386.2; = p.H168Q on NM_139158.2) | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- CDX4 | c.216G>T p.W72C | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CRBN | c.263T>C p.M88T | Missense Mutation (SNP) | VAF 62/482 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- DAPK1 | c.3209A>T p.Q1070L | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DHRS7C | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 44/354 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMSY | c.3947A>T p.Q1316L | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ENPEP | c.961T>C p.Y321H | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA3 | c.1787A>T p.Y596F | Missense Mutation (SNP) | VAF 63/399 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- FGD5 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- FLG | c.11458G>T p.G3820* | Nonsense Mutation (SNP) | VAF 109/964 reads (11%) | called by muse, mutect2, varscan2
- GBA3 | c.287-1G>T p.X96_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | called by muse, varscan2
- GFRA1 | c.1201C>G p.Q401E | Missense Mutation (SNP) | VAF 81/537 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- GRM6 | c.1943C>A p.A648E | Missense Mutation (SNP) | VAF 75/499 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- GRXCR2 | c.698del p.P233Lfs*70 | Frame Shift Del (DEL) | VAF 51/374 reads (14%) | called by mutect2, pindel, varscan2
- HMCN2 | c.13558G>A p.A4520T | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- ITIH4 | c.2179+1G>T p.X727_splice | Splice Site (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2
- KCND2 | c.510G>T p.R170S | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2
- LARP4B | c.623A>T p.D208V | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- LMAN1 | c.601G>C p.V201L | Missense Mutation (SNP) | VAF 62/648 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2
- LRP1B | c.3994C>A p.H1332N | Missense Mutation (SNP) | VAF 44/265 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LTF | c.454C>A p.R152S | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.955); called by muse, mutect2
- MAN2A1 | c.243G>T p.E81D | Missense Mutation (SNP) | VAF 43/285 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- MAPK6 | c.1873del p.Y625Tfs*18 | Frame Shift Del (DEL) | VAF 62/198 reads (31%) | called by mutect2, pindel, varscan2
- METAP1D | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- NAPRT | c.795T>G p.H265Q | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- NBPF4 | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 66/958 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0.232); called by muse, mutect2
- NCOA6 | c.5215A>T p.T1739S | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NKX2-1 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 125/434 reads (29%) | called by muse, mutect2, varscan2
- NRG2 | c.1763A>G p.H588R | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.152); called by muse, mutect2
- OR5F1 | c.475A>T p.N159Y | Missense Mutation (SNP) | VAF 32/323 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.649); called by muse, mutect2
- OR8G2P | c.691A>T p.T231S | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PHIP | c.4532T>A p.V1511E | Missense Mutation (SNP) | VAF 50/380 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- POTEB3 | c.953C>A p.A318E | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, varscan2
- PTBP2 | c.886C>T p.P296S (on ENST00000426398 / NM_001300986.2; = p.P288S on NM_021190.4) | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RAE1 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- RNF17 | c.1156T>A p.S386T | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- SAMD9L | c.2593G>T p.E865* | Nonsense Mutation (SNP) | VAF 17/164 reads (10%) | called by muse, mutect2
- SERPINB12 | c.1100T>A p.V367D | Missense Mutation (SNP) | VAF 40/362 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- SLC52A1 | c.521C>G p.P174R | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SPATA31D1 | c.2774C>A p.S925Y | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- SPEM2 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- SV2B | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 194/633 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- SYT10 | c.207G>T p.L69F | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TMEM132D | c.2803T>G p.L935V | Missense Mutation (SNP) | VAF 134/512 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTLL3 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- UBB | c.596G>C p.G199A | Missense Mutation (SNP) | VAF 77/724 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- WNK1 | c.31A>C p.S11R | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZBTB7A | c.968T>A p.M323K | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF454 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ADCY2 | c.429C>T p.I143= | Silent (SNP) | VAF 34/220 reads (15%) | catalogued as rs776981954, COSV57899799; called by muse, mutect2, varscan2
- AMER1 | c.2154G>T p.L718= | Silent (SNP) | VAF 103/368 reads (28%) | catalogued as COSV57670011; called by muse, mutect2, varscan2
- AOC1 | c.2145C>A p.I715= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as COSV62869128, COSV62871309; called by muse, mutect2, varscan2
- BNC2 | c.1227C>A p.A409= | Silent (SNP) | VAF 34/205 reads (17%) | called by muse, mutect2, varscan2
- CACNA1A | c.2685G>T p.L895= | Silent (SNP) | VAF 29/195 reads (15%) | called by muse, mutect2, varscan2
- CCDC168 | c.16989C>T p.F5663= | Silent (SNP) | VAF 34/271 reads (13%) | called by muse, varscan2
- CD163L1 | c.4215G>A p.E1405= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV58017245; called by muse, mutect2, varscan2
- COL6A2 | c.2628C>T p.R876= | Silent (SNP) | VAF 123/808 reads (15%) | catalogued as rs372413216, COSV52430788; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCTPP1 | c.72C>T p.S24= | Silent (SNP) | VAF 41/215 reads (19%) | called by muse, mutect2, varscan2
- DPP10 | c.1656C>A p.P552= | Silent (SNP) | VAF 23/179 reads (13%) | catalogued as COSV59674948, COSV59736802; called by muse, mutect2, varscan2
- GALNT7 | c.69C>T p.V23= | Silent (SNP) | VAF 58/473 reads (12%) | called by muse, mutect2, varscan2
- GFOD1 | c.87G>A p.K29= | Silent (SNP) | VAF 71/494 reads (14%) | called by muse, mutect2, varscan2
- GSE1 | c.2799G>T p.P933= | Silent (SNP) | VAF 96/712 reads (13%) | catalogued as rs752892296; called by muse, mutect2, varscan2
- ITGAX | c.690C>A p.T230= | Silent (SNP) | VAF 68/270 reads (25%) | called by muse, mutect2, varscan2
- ITIH1 | c.2466G>T p.R822= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as rs1408289145, COSV56252963; called by muse, mutect2, varscan2
- KHSRP | c.1374A>C p.V458= | Silent (SNP) | VAF 44/222 reads (20%) | called by muse, mutect2, varscan2
- KIAA2026 | c.4170A>G p.S1390= | Silent (SNP) | VAF 36/236 reads (15%) | called by muse, mutect2, varscan2
- KLHDC9 | c.954C>T p.R318= | Silent (SNP) | VAF 29/390 reads (7%) | called by muse, mutect2
- LINS1 | c.468A>G p.L156= | Silent (SNP) | VAF 42/389 reads (11%) | catalogued as rs759906898; called by muse, mutect2, varscan2
- MAP4K1 | c.1599G>A p.T533= | Silent (SNP) | VAF 37/181 reads (20%) | catalogued as rs772511208; called by muse, mutect2, varscan2
- MATK | c.654G>A p.S218= (on ENST00000310132 / NM_139355.3; = p.S219= on NM_002378.4) | Silent (SNP) | VAF 60/457 reads (13%) | catalogued as rs925604530; called by muse, mutect2, varscan2
- MECOM | c.69C>T p.C23= (on ENST00000468789 / NM_001105078.4; = p.C211= on NM_004991.4) | Silent (SNP) | VAF 56/345 reads (16%) | catalogued as rs188482846, COSV52976360; called by muse, mutect2, varscan2
- MROH9 | c.1155A>G p.K385= | Silent (SNP) | VAF 41/302 reads (14%) | called by muse, varscan2
- NRIP1 | c.699G>A p.P233= | Silent (SNP) | VAF 41/310 reads (13%) | catalogued as rs190171837; called by muse, mutect2, varscan2
- OLFML2B | c.711C>T p.Y237= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as rs367586166; called by muse, mutect2
- PCDH11X | c.21G>T p.T7= | Silent (SNP) | VAF 91/317 reads (29%) | catalogued as rs138686525, COSV53451819; called by muse, mutect2, varscan2
- RADIL | c.3105G>A p.L1035= | Silent (SNP) | VAF 21/123 reads (17%) | called by muse, mutect2, varscan2
- SGCZ | c.357G>A p.Q119= | Silent (SNP) | VAF 45/306 reads (15%) | catalogued as rs771489541; called by muse, mutect2, varscan2
- WFDC5 | c.30G>T p.G10= | Silent (SNP) | VAF 46/209 reads (22%) | called by muse, mutect2, varscan2
- ZFP42 | c.894G>T p.T298= | Silent (SNP) | VAF 18/104 reads (17%) | called by muse, mutect2
- ZNF250 | c.1452T>C p.C484= | Silent (SNP) | VAF 55/396 reads (14%) | called by muse, mutect2, varscan2
- ZNF879 | c.654C>T p.S218= | Silent (SNP) | VAF 23/149 reads (15%) | called by muse, mutect2, varscan2
- ACBD5 | chr10:27195945 C>G | 3'Flank (SNP) | VAF 6/88 reads (7%) | catalogued as rs1475586677; called by muse, mutect2
- AFAP1L1 | c.1020+55G>T | Intron (SNP) | VAF 50/362 reads (14%) | called by muse, varscan2
- ARHGAP20 | c.*2203T>C | 3'UTR (SNP) | VAF 15/127 reads (12%) | called by muse, mutect2, varscan2
- CD6 | c.1943-10C>A | Intron (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
- CMC1 | c.20-9539G>C | Intron (SNP) | VAF 23/231 reads (10%) | called by muse, mutect2, varscan2
- ETFB | c.58-225C>T | Intron (SNP) | VAF 70/604 reads (12%) | catalogued as rs201291204; called by muse, mutect2, varscan2
- FAM20A | c.*1159del | 3'UTR (DEL) | VAF 28/215 reads (13%) | called by mutect2, pindel, varscan2
- GUCY1B1 | c.1176-53A>T | Intron (SNP) | VAF 32/241 reads (13%) | called by muse, mutect2, varscan2
- NDUFA5 | c.66+380C>G | Intron (SNP) | VAF 35/259 reads (14%) | called by muse, mutect2, varscan2
- PLEKHO1 | c.-14C>T | 5'UTR (SNP) | VAF 22/104 reads (21%) | called by muse, mutect2, varscan2
- PTPRS | c.3923+42G>T | Intron (SNP) | VAF 34/243 reads (14%) | called by muse, mutect2, varscan2
- RRM2 | chr2:10122664 G>C | 5'Flank (SNP) | VAF 9/86 reads (10%) | catalogued as COSV58816007; called by mutect2, varscan2
- TEX35 | c.-15C>A | 5'UTR (SNP) | VAF 42/322 reads (13%) | called by muse, mutect2, varscan2
- TNNT3 | chr11:1938636 G>A | 3'Flank (SNP) | VAF 39/326 reads (12%) | catalogued as rs573740589, COSV53485219; called by muse, mutect2, varscan2
- TRIM22 | chr11:5714721 G>C | 3'Flank (SNP) | VAF 4/53 reads (8%) | catalogued as rs986073100; called by muse, mutect2
- TUBB8P7 | n.1081T>A | RNA (SNP) | VAF 92/788 reads (12%) | called by muse, varscan2
- ZNF711 | c.917-948C>T | Intron (SNP) | VAF 25/140 reads (18%) | called by muse, mutect2, varscan2
- ZNF717 | c.184+29G>T | Intron (SNP) | VAF 25/296 reads (8%) | called by muse, mutect2
- ZNF717 | c.184+28G>T | Intron (SNP) | VAF 26/300 reads (9%) | catalogued as rs202161426; called by muse, mutect2
